Somatic mutation profile of tumor specimen TCGA-CI-6619-01B (aliquot TCGA-CI-6619-01B-11D-1826-10) from TCGA case TCGA-CI-6619, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 41.9 years (15,322 days).
Specimen TCGA-CI-6619-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b85a6ee-582a-4eeb-a217-796dde52c9dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CI-6619-10A (Blood Derived Normal), aliquot TCGA-CI-6619-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/908d0aa9-3235-4829-a7f6-ba773e86fcec

The open-access MAF lists 65 somatic variants for this specimen: 47 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 17, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4067C>G p.S1356* | Nonsense Mutation (SNP) | VAF 20/36 reads (56%) | catalogued as rs1554085480, COSV57325773, COSV57330189, COSV57333960; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACAT2 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100365036; called by muse, mutect2, varscan2
- ACHE | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs771862488, COSV53821350; called by muse, mutect2, varscan2
- APOB | c.9010G>T p.A3004S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV99267344; called by muse, mutect2, varscan2
- ARAP3 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs149532200; called by muse, mutect2, varscan2
- CCKAR | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs115488558; called by muse, mutect2, varscan2
- CFAP44 | c.2547G>T p.W849C | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1451881403, COSV55615620; called by muse, mutect2, varscan2
- CHD8 | c.2844T>A p.D948E (on ENST00000646647 / NM_001170629.2; = p.D669E on NM_020920.4) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67872605; called by muse, mutect2, varscan2
- CHDH | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs756969396, COSV59459939; called by muse, mutect2, varscan2
- CLSPN | c.3001T>A p.F1001I | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV52056846; called by muse, mutect2, varscan2
- CNBD1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.012); catalogued as COSV72917556; called by muse, mutect2
- CNOT1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs1178995793, COSV57779803; called by muse, mutect2, varscan2
- DISP3 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs748054963, COSV53836987; called by muse, mutect2, varscan2
- DMXL1 | c.1772G>A p.S591N | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as COSV60720389; called by muse, mutect2, varscan2
- ELMO2 | c.1799A>T p.K600I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV51685992; called by muse, mutect2, varscan2
- ETS1 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as rs774575276, COSV60097292; called by muse, mutect2, varscan2
- HDDC3 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100376622; called by muse, mutect2
- HOXC10 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV57727067, COSV57727299; called by muse, mutect2, varscan2
- IL9R | c.130G>T p.G44W | Missense Mutation (SNP) | VAF 59/256 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV54902105; called by muse, mutect2, varscan2
- LIMA1 | c.1879G>C p.G627R | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV57968393; called by muse, mutect2, varscan2
- LRRC31 | c.1235A>G p.K412R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV52982896; called by muse, mutect2, varscan2
- MIS18BP1 | c.218del p.N73Ifs*8 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as COSV100173031; called by mutect2, varscan2
- MUCL1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.346); catalogued as rs768368179, COSV58193749; called by muse, mutect2, varscan2
- NHP2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1214412834, COSV99200954; called by muse, mutect2, varscan2
- NMT2 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs540952796, COSV65382035; called by muse, mutect2, varscan2
- NPHP4 | c.3650G>A p.R1217H | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.052); catalogued as rs1389043961, COSV65397672; called by muse, mutect2, varscan2
- P2RX7 | c.329A>G p.K110R | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.059); catalogued as COSV99947699; called by muse, mutect2
- PGAP3 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV56132842; called by muse, mutect2, varscan2
- PHF3 | c.4571A>T p.K1524I | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as COSV100013802; called by muse, mutect2
- POLR3E | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1197228508, COSV100242329; called by muse, mutect2, varscan2
- PPM1F | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs144940091, COSV54286540; called by muse, mutect2, varscan2
- PTPRA | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53788416; called by muse, mutect2
- PTPRH | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs369140474; called by muse, mutect2
- PUM1 | c.2591+2T>G p.X864_splice | Splice Site (SNP) | VAF 15/43 reads (35%) | catalogued as COSV57091000; called by muse, mutect2, varscan2
- PYHIN1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | PolyPhen benign (0.255); catalogued as rs375227792, COSV100932656, COSV63730479; called by muse, mutect2
- RAB3C | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs199850819, COSV51442049; called by muse, mutect2, varscan2
- ROBO3 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs373820994; called by muse, mutect2, varscan2
- SEZ6L2 | c.1004G>A p.R335Q (on ENST00000308713 / NM_001114099.3; = p.R265Q on NM_012410.4) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.109); catalogued as rs556280590, COSV58103023; called by muse, mutect2, varscan2
- SLITRK5 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs371327441; called by muse, mutect2, varscan2
- SMARCD1 | c.1548G>C p.*516Yext*23 | Nonstop Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV56547504, COSV99993861; called by muse, mutect2, varscan2
- SMARCD3 | c.839G>A p.R280H (on ENST00000262188 / NM_001003801.2; = p.R267H on NM_003078.4) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs139896646; called by muse, mutect2, varscan2
- TCF7L2 | c.1772A>G p.Q591R (on ENST00000355995 / NM_001367943.1; = p.Q568R on NM_030756.5) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated, low confidence (0.62); PolyPhen possibly damaging (0.885); catalogued as COSV99526549; called by muse, mutect2, varscan2
- THSD7B | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as rs750153977, COSV55661886; called by muse, mutect2, varscan2
- USP1 | c.1985del p.N662Mfs*2 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs751218576; ClinVar: not provided; called by mutect2, varscan2
- ZNF224 | c.1829C>G p.T610S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV61243416; called by muse, mutect2, varscan2
- FBXW7 | c.820_824del p.P274Vfs*11 (on ENST00000281708 / NM_001349798.2; = p.P194Vfs*11 on NM_018315.5) | Frame Shift Del (DEL) | VAF 33/115 reads (29%) | called by mutect2, pindel, varscan2
- ATG2A | c.1812C>G p.A604= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV65968798; called by muse, mutect2, varscan2
- CCNF | c.1389G>A p.T463= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs200891175, COSV99564036; called by muse, mutect2, varscan2
- CHSY3 | c.837C>T p.N279= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV59287736; called by muse, mutect2, varscan2
- DMD | c.606C>T p.I202= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs138335295, COSV55899806; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- FAM167B | c.12G>C p.G4= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV100405378, COSV61111282; called by muse, mutect2, varscan2
- KCNH8 | c.1113G>A p.A371= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs754907543, COSV60460915, COSV60475965; called by muse, mutect2, varscan2
- LIPC | c.1197G>A p.T399= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs560051123, COSV100134810, COSV54423760; called by muse, mutect2, varscan2
- MTTP | c.450A>G p.R150= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99645484; called by muse, varscan2
- MYF5 | c.102G>A p.P34= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV57357334; called by muse, varscan2
- OAS3 | c.1206G>A p.P402= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs781020247, COSV57448963; called by muse, mutect2, varscan2
- PSD | c.1329G>A p.E443= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs774484666, COSV50060119; called by muse, mutect2, varscan2
- SLC24A5 | c.963C>G p.T321= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV99982014; called by muse, mutect2, varscan2
- TEX14 | c.2031G>A p.A677= (on ENST00000240361 / NM_001201457.2; = p.A671= on NM_031272.5) | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs142675831; called by muse, mutect2, varscan2
- TRPM4 | c.2808C>T p.F936= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV53268503; called by muse, mutect2, varscan2
- VEGFC | c.174G>A p.E58= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV99709934; called by muse, mutect2
- ZPBP | c.348T>G p.T116= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99250288; called by muse, mutect2
- ZW10 | c.1968A>G p.L656= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV52319229; called by muse, mutect2, varscan2
- CSH1 | c.457-35C>T | Intron (SNP) | VAF 11/112 reads (10%) | catalogued as rs749564716, COSV60241902; called by muse, mutect2, varscan2
